Gene-level copy-number profile of tumor specimen ALCH-B3FG-TTP1-B from ALCHEMIST case ALCH-B3FG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.8 years (23,658 days).
Specimen ALCH-B3FG-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d85b19e3-8e81-40d6-b859-42355f469c41.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/b393adcd-e5d5-4abf-a51e-9f2726d88ec3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 3,484; copy number 2: 53,880; copy number 3: 904; copy number 4: 35; copy number 5: 24; copy number 6: 15; copy number 7: 18; copy number 8: 2; copy number 9: 1; copy number 10: 12; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:231,559,903–231,560,364, 1 gene: RPL21P35.
- chr9:137,423,350–137,441,816, 2 genes: NOXA1, ENTPD8.
- chr10:72,216,000–72,235,860, 2 genes (within-gene range 0–2): ANAPC16, Y_RNA.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr16:87,834,592–87,834,660, 1 gene (within-gene range 0–3): MIR6775.
- chr16:87,892,955–87,893,735, 1 gene (within-gene range 0–2): AC133539.1.
- chr17:782,353–795,794, 3 genes (within-gene range 0–2): MRM3, AC087392.4, AC087392.5.
- chr17:46,259,551–46,260,606, 1 gene: AC005829.2.
- chr20:51,902,291–51,902,395, 1 gene: RNU6-347P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 73 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,280,436–1,292,029, 1 gene, copy number 18: SCNN1D.
- chr1:2,632,568–2,636,620, 1 gene, copy number 8 (within-gene range 2–8): MMEL1-AS1.
- chr4:836,512–837,224, 1 gene, copy number 5: AC139887.3.
- chr8:143,437,659–143,609,773, 13 genes, copy number 5: ZC3H3, AC067930.9, AC067930.3, RN7SKP175, GSDMD, MROH6, AC067930.4, NAPRT, AC067930.5, AC067930.1, EEF1D, TIGD5, PYCR3.
- chr8:144,012,280–144,118,328, 12 genes, copy number 6 (within-gene range 3–6): SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1, WDR97.
- chr9:136,612,024–136,617,181, 1 gene, copy number 9: LINC01451.
- chr16:629,239–667,833, 6 genes, copy number 10 (within-gene range 1–10): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr16:678,504–692,554, 6 genes, copy number 10 (within-gene range 4–10): LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1.
- chr16:817,489–862,843, 1 gene, copy number 5 (within-gene range 4–5): AL023882.1.
- chr16:853,634–1,263,845, 26 genes, copy number 5–7: LMF1, AL031716.1, AL008727.1, LMF1-AS1, AC009041.3, CEROX1, SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2, TPSAB1, TPSD1, AC120498.2, PRSS29P.
- chr17:46,372,855–46,509,339, 2 genes, copy number 5–6: NSFP1, RDM1P2.
- chr19:47,484,282–47,501,597, 1 gene, copy number 6 (within-gene range 2–6): NAPA-AS1.
- chr22:20,299,760–20,321,203, 2 genes, copy number 6–8: AC007663.1, AC007663.3.

Autosomal genes at a single copy (total copy number 1): 3,449. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
